Somatic mutation profile of tumor specimen TCGA-FS-A1ZB-06A (aliquot TCGA-FS-A1ZB-06A-12D-A197-08) from TCGA case TCGA-FS-A1ZB, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 61.2 years (22,346 days).
Specimen TCGA-FS-A1ZB-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d284795c-97bd-42d3-9ea3-88c7b20adeaf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A1ZB-10A (Blood Derived Normal), aliquot TCGA-FS-A1ZB-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46587de9-0d12-4dd7-802b-0b0f37db1e0d

The open-access MAF lists 255 somatic variants for this specimen: 172 protein-altering or splice-affecting, 76 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 160, Silent 76, Nonsense Mutation 6, Intron 5, Splice Region 3, Splice Site 2, Frame Shift Del 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 62/186 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ABCA13 | c.6449C>T p.T2150I | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV70041233; called by muse, mutect2, varscan2
- AC090517.4 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750538277, COSV50997563, COSV50999727; called by muse, mutect2, varscan2
- ACTN2 | c.1529T>C p.L510S | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.718); catalogued as COSV63977562; called by muse, mutect2, varscan2
- ADARB2 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs867672739, COSV67219714; called by muse, mutect2, varscan2
- AGTR1 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV62557919; called by muse, mutect2, varscan2
- ALPK2 | c.4063G>A p.D1355N | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs760413335, COSV64495977; called by muse, mutect2, varscan2
- ANKRD13C | c.394A>G p.I132V | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.625); catalogued as COSV52034177; called by muse, mutect2
- AQP9 | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.277); catalogued as COSV54970224; called by muse, mutect2, varscan2
- AQP9 | c.291G>A p.M97I | Missense Mutation (SNP) | VAF 70/284 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as COSV54969360, COSV54971869; called by muse, varscan2
- ARID5A | c.1116G>C p.L372F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV62591666, COSV62591859; called by muse, mutect2
- ARL11 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.759); catalogued as COSV56291993; called by muse, mutect2, varscan2
- ARVCF | c.499T>C p.F167L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV54269360; called by muse, varscan2
- ASXL3 | c.3562C>T p.P1188S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.162); catalogued as rs1568364767, COSV52476118, COSV52478641; called by muse, mutect2, varscan2
- ATAD5 | c.5095G>A p.G1699R | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as COSV58977893; called by muse, mutect2, varscan2
- BCAS3 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as rs767397116, COSV66780241; called by muse, mutect2, varscan2
- BRINP3 | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.108); catalogued as COSV100819139, COSV66537342; called by mutect2, varscan2
- BTF3 | c.139G>C p.E47Q (on ENST00000380591 / NM_001037637.1; = p.E3Q on NM_001207.4) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.831); catalogued as COSV60063819; called by muse, mutect2, varscan2
- C1QL3 | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54346899; called by muse, mutect2, varscan2
- C1orf87 | c.1589C>T p.S530L | Missense Mutation (SNP) | VAF 54/220 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs759893988, COSV64596223; called by mutect2, varscan2
- C9orf131 | c.2252G>A p.G751E | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as COSV56612409; called by muse, mutect2, varscan2
- CAMK1D | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 63/282 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.067); catalogued as COSV66618078; called by muse, mutect2, varscan2
- CASS4 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV64386404, COSV64388016; called by muse, mutect2, varscan2
- CATSPER2 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58660523; called by muse, mutect2, varscan2
- CBLB | c.1748C>T p.S583F | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.276); catalogued as COSV99913725; called by mutect2, varscan2
- CCDC141 | c.2533C>T p.L845F | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as COSV55380265; called by muse, mutect2, varscan2
- CCDC181 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.756); catalogued as COSV63157725; called by muse, mutect2, varscan2
- CCDC33 | c.1817G>A p.G606E | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as COSV51502624; called by muse, mutect2, varscan2
- CCR2 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 103/416 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.612); catalogued as COSV52747831; called by muse, mutect2, varscan2
- CD200R1 | c.613C>T p.H205Y (on ENST00000471858 / NM_170780.3; = p.H228Y on NM_138806.4) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.905); catalogued as COSV55602952; called by muse, mutect2, varscan2
- CD34 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1483955349, COSV60414619; called by mutect2, varscan2
- CDH9 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV50400503; called by muse, mutect2, varscan2
- CGNL1 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as COSV55573611; called by muse, mutect2, varscan2
- CHD1L | c.1018G>T p.D340Y | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV63615098; called by mutect2, varscan2
- CHD6 | c.7316C>T p.P2439L | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as COSV64693546; called by muse, mutect2, varscan2
- CHRM2 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57781823; called by muse, mutect2, varscan2
- CIP2A | c.1624C>T p.P542S | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV55420725; called by muse, mutect2, varscan2
- COL28A1 | c.1222C>T p.P408S | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV68084008; called by muse, mutect2, varscan2
- CYP26B1 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs142987158, COSV50010938; called by muse, mutect2, varscan2
- CYP2C18 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as rs774541514, COSV53674491; called by muse, mutect2, varscan2
- DCAF4L2 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV60477788, COSV60478000; called by mutect2, varscan2
- DDX11 | c.2370C>T p.G790= (on ENST00000545668 / NM_152438.2; = p.G740= on NM_004399.3) | Splice Region (SNP) | VAF 18/49 reads (37%) | catalogued as COSV52506189; called by muse, mutect2
- DENND2A | c.2911G>A p.G971S | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV52050169, COSV52057210; called by muse, mutect2, varscan2
- DGKE | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV52350184; called by mutect2, varscan2
- DNAH10 | c.4253T>C p.V1418A (on ENST00000409039; = p.V1357A on NM_207437.3) | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as COSV68999502; called by muse, mutect2, varscan2
- EIF2AK4 | c.2542G>A p.D848N | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs768944097, COSV55465508; called by muse, mutect2, varscan2
- ELMO2 | c.365A>G p.N122S | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.03); catalogued as rs1240780094, COSV51685397; called by muse, mutect2, varscan2
- ELOVL3 | c.384C>T p.L128= | Splice Region (SNP) | VAF 26/98 reads (27%) | catalogued as rs540283969, COSV64174652, COSV64174892; called by mutect2, varscan2
- ERICH3 | c.3742C>T p.H1248Y | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV58615256; called by mutect2, varscan2
- F2 | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61317269; called by muse, mutect2, varscan2
- FAM135B | c.2361C>A p.D787E | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV52747252; called by muse, mutect2, varscan2
- FLG | c.8696G>A p.G2899E | Missense Mutation (SNP) | VAF 34/389 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.544); catalogued as rs1304111714, COSV64246806; called by muse, mutect2
- FLG | c.6523G>A p.G2175R | Missense Mutation (SNP) | VAF 39/480 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs1240217339, COSV64246811; called by muse, mutect2
- FLT1 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.077); catalogued as rs866351272, COSV56723126; called by mutect2, varscan2
- FRY | c.6763C>T p.L2255F | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.37); catalogued as rs1419505849, COSV66577060; called by muse, mutect2, varscan2
- GALNT13 | c.994T>A p.S332T | Missense Mutation (SNP) | VAF 44/250 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV67234401; called by mutect2, varscan2
- GAS2 | c.403G>A p.G135S | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV53411412; called by muse, mutect2, varscan2
- GPC5 | c.1256G>A p.W419* | Nonsense Mutation (SNP) | VAF 22/89 reads (25%) | catalogued as COSV100996361, COSV65586658; called by muse, mutect2, varscan2
- GPD2 | c.1658C>T p.S553L | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV60095878; called by mutect2, varscan2
- GPR39 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.793); catalogued as rs1182398835, COSV61424624; called by muse, mutect2, varscan2
- GRIA4 | c.452G>A p.W151* | Nonsense Mutation (SNP) | VAF 103/194 reads (53%) | catalogued as COSV56914404; called by muse, mutect2, varscan2
- GYS2 | c.1459C>T p.P487S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.911); catalogued as COSV53927372, COSV53929120; called by mutect2, varscan2
- HBE1 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99496304; called by muse, mutect2, varscan2
- HSF1 | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.646); catalogued as COSV60049040; called by muse, mutect2, varscan2
- IKZF2 | c.463C>T p.L155F | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59582711; called by muse, mutect2, varscan2
- ISL2 | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV51958979; called by muse, mutect2, varscan2
- ITGA4 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV52003126; called by muse, mutect2, varscan2
- ITIH2 | c.2257G>A p.G753R | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as rs370155766; called by muse, mutect2, varscan2
- IVL | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.203); catalogued as COSV64216858; called by muse, mutect2, varscan2
- JAG1 | c.1523G>A p.R508K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV54761587; called by muse, mutect2, varscan2
- KCNK10 | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.003); catalogued as rs769621803, COSV56650717; called by muse, varscan2
- KCNK3 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 48/253 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57194165; called by muse, varscan2
- KIAA1217 | c.2804C>T p.S935F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100286847; called by mutect2, varscan2
- KLHL32 | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as rs1341947706, COSV65111807; called by muse, mutect2, varscan2
- KRT31 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52433582; called by muse, mutect2, varscan2
- KRT37 | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0.038); catalogued as COSV56656757; called by muse, varscan2
- LHCGR | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54301666; called by muse, mutect2, varscan2
- MAGEB1 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs754534422, COSV66775762; called by mutect2, varscan2
- MAP3K20 | c.2000C>T p.S667F | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV64379942; called by muse, mutect2, varscan2
- MATR3 | c.1776C>T p.S592= | Splice Region (SNP) | VAF 10/34 reads (29%) | catalogued as COSV63079227; called by mutect2, varscan2
- MGAM | c.4009G>A p.D1337N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV72075387; called by mutect2, varscan2
- MPP7 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61736792; called by muse, mutect2, varscan2
- MRPL54 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV57463464; called by muse, mutect2, varscan2
- MTRF1 | c.76C>T p.H26Y | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV53482054; called by muse, mutect2, varscan2
- MYH4 | c.4615C>T p.H1539Y | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV55124178; called by mutect2, varscan2
- MYH4 | c.2502G>A p.M834I | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs1408526493, COSV55124183; called by mutect2, varscan2
- MYO1A | c.2065C>T p.L689F | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55654202; called by muse, mutect2, varscan2
- MYO9A | c.3877C>T p.R1293C | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1307006954, COSV61848277; called by mutect2, varscan2
- NEMF | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.348); catalogued as rs1189684737, COSV53594482; called by muse, mutect2, varscan2
- NIBAN1 | c.696G>A p.M232I | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV62287139; called by mutect2, varscan2
- NLRP5 | c.1973C>T p.P658L | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.269); catalogued as COSV66766495; called by muse, mutect2, varscan2
- NUAK1 | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1344362979, COSV104372948, COSV54607131; called by muse, mutect2, varscan2
- NXF3 | c.482G>A p.S161N | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.056); catalogued as COSV67704840; called by muse, mutect2, varscan2
- OPRK1 | c.757C>T p.L253F | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1203218600, COSV55573102; called by muse, mutect2, varscan2
- OR2M5 | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 54/224 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV63546865; called by muse, mutect2, varscan2
- OR2T1 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.612); catalogued as rs773551608, COSV63541388; called by mutect2, varscan2
- OR4E2 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs369264275; called by mutect2, varscan2
- OR4K15 | c.471G>A p.M157I (on ENST00000305051; = p.M133I on NM_001005486.1) | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV59303024; called by mutect2, varscan2
- P2RY2 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as rs773984399, COSV60777439; called by mutect2, varscan2
- PALM2AKAP2 | c.268G>A p.E90K (on ENST00000374531 / NM_001037293.2; = p.E88K on NM_007203.5) | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57129934; called by muse, mutect2, varscan2
- PAPPA | c.4234C>T p.P1412S | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.685); catalogued as COSV60282134, COSV60282940; called by muse, mutect2, varscan2
- PARD3B | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV62526012; called by muse, mutect2, varscan2
- PCDH15 | c.1244C>T p.S415L | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.426); catalogued as rs747154146, COSV57374587; called by mutect2, varscan2
- PCDHB10 | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.049); catalogued as rs782399537, COSV53382593; called by muse, mutect2, varscan2
- PCDHB3 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV50564787; called by mutect2, varscan2
- PCNX2 | c.3470C>T p.S1157L | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV50786811; called by mutect2, varscan2
- PDGFRA | c.1122-1G>A p.X374_splice | Splice Site (SNP) | VAF 19/106 reads (18%) | catalogued as COSV57272152; called by muse, mutect2, varscan2
- PGLYRP4 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs148847664, COSV62834555; called by mutect2, varscan2
- PGS1 | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as rs79039614; called by muse, mutect2, varscan2
- PIK3R5 | c.1161G>A p.M387I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as rs1408705829, COSV52657507; called by muse, mutect2, varscan2
- PKHD1L1 | c.5225C>T p.S1742L | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as COSV65747422; called by muse, mutect2, varscan2
- PLCE1 | c.3500C>T p.P1167L | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.209); catalogued as COSV53366773; called by muse, mutect2, varscan2
- PLEKHG3 | c.2993G>A p.C998Y (on ENST00000394691; = p.C1054Y on NM_001308147.2) | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.583); catalogued as COSV55982829; called by mutect2, varscan2
- PNPLA6 | c.3176C>T p.S1059F (on ENST00000414982 / NM_001166111.2; = p.S1011F on NM_006702.5) | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV55383463; called by muse, mutect2, varscan2
- POU1F1 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV60157236; called by muse, mutect2, varscan2
- PRAMEF18 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 38/318 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as rs1553188524; called by mutect2, varscan2
- PROSER1 | c.1784C>T p.S595L | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.053); catalogued as rs753324795, COSV104415499, COSV61489119; called by mutect2, varscan2
- PRR15L | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.24); catalogued as rs780907946, COSV56024453; called by mutect2, varscan2
- PTCHD3 | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs755906338, COSV101438926; called by muse, mutect2, varscan2
- PTPRF | c.3691C>T p.P1231S | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1209338659, COSV100741013; called by muse, mutect2, varscan2
- PWWP3B | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.187); catalogued as COSV61801323; called by muse, mutect2, varscan2
- RAB3IP | c.478C>T p.R160C (on ENST00000550536 / NM_175623.4; = p.R144C on NM_022456.5) | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs375092922, COSV56083543; called by mutect2, varscan2
- RAP1GAP | c.1562A>G p.K521R | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV51576694; called by muse, mutect2, varscan2
- RSRC1 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.725); catalogued as rs764077777, COSV55836606; called by mutect2, varscan2
- RUNDC3B | c.1244G>A p.G415E | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV56696166; called by muse, varscan2
- RYR3 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs776257846, COSV66793170; called by mutect2, varscan2
- SAGE1 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV61016722; called by muse, mutect2, varscan2
- SCN2A | c.3520+1G>A p.X1174_splice | Splice Site (SNP) | VAF 20/70 reads (29%) | catalogued as COSV51852398; called by muse, mutect2, varscan2
- SDR9C7 | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs756591404, COSV53290401, COSV99524559; called by muse, mutect2, varscan2
- SEC24D | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763522207, COSV54883744; called by muse, mutect2, varscan2
- SERPINA10 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs267604109, COSV56228009; called by mutect2, varscan2
- SERTAD4 | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV65399939; called by muse, mutect2, varscan2
- SLC12A5 | c.1705G>A p.E569K (on ENST00000454036 / NM_001134771.2; = p.E546K on NM_020708.5) | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV54799957; called by muse, mutect2, varscan2
- SLC1A5 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV69466733; called by muse, mutect2, varscan2
- SLC7A2 | c.1145C>T p.S382F | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV50267984; called by muse, mutect2, varscan2
- SP140L | c.290G>A p.R97K | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as COSV54747157; called by muse, mutect2, varscan2
- SPEG | c.3995G>A p.W1332* | Nonsense Mutation (SNP) | VAF 17/33 reads (52%) | catalogued as COSV56663270; called by muse, mutect2, varscan2
- SPINK5 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.184); catalogued as COSV56248420, COSV56260549; called by muse, mutect2, varscan2
- SRGAP3 | c.2500G>A p.D834N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.959); catalogued as COSV64532294; called by mutect2, varscan2
- ST7 | c.1658C>T p.S553L | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.053); catalogued as rs370892077; called by mutect2, varscan2
- SV2B | c.1894G>A p.G632R | Missense Mutation (SNP) | VAF 132/531 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV57700712; called by muse, mutect2, varscan2
- SYNE1 | c.969G>A p.M323I (on ENST00000367255 / NM_182961.4; = p.M330I on NM_033071.3) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV55071867; called by muse, mutect2, varscan2
- TANGO2 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100530094; called by muse, mutect2, varscan2
- TARBP1 | c.3859C>T p.R1287* | Nonsense Mutation (SNP) | VAF 28/110 reads (25%) | catalogued as rs201259533, COSV50192818, COSV50194605; called by mutect2, varscan2
- TEX2 | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51984750; called by muse, varscan2
- TMPRSS9 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1459755959, COSV60230505; called by muse, mutect2, varscan2
- TNFRSF11B | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV52073411; called by mutect2, varscan2
- TNNT2 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.147); catalogued as rs765359025, COSV52664907; called by muse, mutect2, varscan2
- TRHR | c.272G>A p.W91* | Nonsense Mutation (SNP) | VAF 30/124 reads (24%) | catalogued as COSV61235973; called by muse, varscan2
- TRPM4 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs376782481; called by muse, mutect2, varscan2
- TRRAP | c.2165C>T p.S722F | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs147405090, COSV62839126, COSV62849075; called by muse, mutect2, varscan2
- TSNARE1 | c.1091C>T p.S364F | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56173077; called by muse, mutect2, varscan2
- TTN | c.24658G>A p.D8220N (on ENST00000591111; = p.D7293N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | PolyPhen possibly damaging (0.582); catalogued as COSV60267847, COSV60274928; called by muse, mutect2, varscan2
- TTN | c.10339G>A p.E3447K (on ENST00000591111; = p.E3401K on NM_003319.4) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | PolyPhen benign (0.003); catalogued as COSV60274952; called by muse, mutect2, varscan2
- UGT2A3 | c.1369C>T p.R457* | Nonsense Mutation (SNP) | VAF 15/93 reads (16%) | catalogued as rs267600216, COSV52359885, COSV52360393; called by mutect2, varscan2
- USP17L2 | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs1456864120, COSV61555645; called by muse, varscan2
- VIL1 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs769427100, COSV50294320; called by muse, mutect2, varscan2
- VPS13D | c.6977C>T p.S2326F | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1207188089, COSV50669057; called by muse, mutect2, varscan2
- VSTM4 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868605767, COSV53678165; called by muse, mutect2, varscan2
- VWF | c.1001G>A p.G334E | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs932134873, CM1211905, COSV99779453; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- XIRP2 | c.6790G>A p.D2264N (on ENST00000628543; = p.D2439N on NM_152381.6) | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs563915541, COSV54679859; called by mutect2, varscan2
- ZBTB8A | c.923G>A p.R308K | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); catalogued as COSV100331534, COSV57143863; called by muse, mutect2, varscan2
- ZDBF2 | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs1377376150, COSV100985075; called by muse, mutect2, varscan2
- ZDBF2 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs541984086, COSV65623099; called by mutect2, varscan2
- ZNF536 | c.2254G>A p.D752N | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV62831838; called by muse, mutect2, varscan2
- ZNF777 | c.1861C>T p.P621S | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV56099536; called by muse, mutect2, varscan2
- ZNF831 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV64044036; called by muse, mutect2, varscan2
- ZNF883 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.065); catalogued as rs1375768397, COSV71309089; called by mutect2, varscan2
- ZSCAN18 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV53736426; called by muse, mutect2, varscan2
- GAS2L2 | c.739C>T p.L247F | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JAK2 | c.1015del p.S339Afs*4 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- TRBV28 | c.193A>G p.I65V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- ADAMTS9 | c.3153C>T p.F1051= | Silent (SNP) | VAF 123/502 reads (25%) | catalogued as COSV55785397; called by muse, varscan2
- AHNAK2 | c.8757G>A p.K2919= | Silent (SNP) | VAF 67/256 reads (26%) | catalogued as COSV60926741; called by muse, mutect2, varscan2
- ANKRD22 | c.453C>T p.I151= | Silent (SNP) | VAF 50/190 reads (26%) | catalogued as COSV64237015; called by muse, mutect2, varscan2
- ANO4 | c.2340C>T p.L780= (on ENST00000392977 / NM_001286615.2; = p.L745= on NM_178826.4) | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as rs758995911, COSV100153024, COSV54608910; called by muse, varscan2
- APOBEC3F | c.774C>T p.F258= | Silent (SNP) | VAF 47/217 reads (22%) | catalogued as COSV100415221; called by muse, mutect2, varscan2
- AQP9 | c.318G>A p.V106= | Silent (SNP) | VAF 58/244 reads (24%) | catalogued as COSV54968764, COSV54970252; called by muse, varscan2
- ARSD | c.1050C>T p.F350= | Silent (SNP) | VAF 39/80 reads (49%) | catalogued as COSV54202459; called by mutect2, varscan2
- ATP6V1B1 | c.1317C>T p.T439= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs782106373, COSV52271197; called by muse, mutect2, varscan2
- C3orf56 | c.522C>T p.S174= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV67756452; called by mutect2, varscan2
- CCDC141 | c.3903C>T p.T1301= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV55380246; called by muse, mutect2, varscan2
- CDH20 | c.1014G>A p.K338= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs1476680433, COSV53016041; called by mutect2, varscan2
- COL7A1 | c.5946G>A p.G1982= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs1264042847, COSV60401463; called by muse, mutect2, varscan2
- CRYGC | c.477C>T p.A159= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV52205935; called by muse, varscan2
- CSMD2 | c.7614G>A p.K2538= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as COSV53949358; called by muse, mutect2, varscan2
- CSMD2 | c.4407G>A p.K1469= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as COSV53949376; called by muse, mutect2
- CYP27A1 | c.1578C>T p.F526= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV51468710; called by muse, mutect2, varscan2
- DYSF | c.240C>T p.F80= | Silent (SNP) | VAF 24/130 reads (18%) | catalogued as rs267599437, COSV50532794; called by muse, mutect2, varscan2
- FBXO38 | c.1585C>T p.L529= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs1424326950, COSV57030723; called by muse, varscan2
- FCGR1A | c.462C>T p.T154= | Silent (SNP) | VAF 20/171 reads (12%) | catalogued as COSV100977297; called by muse, mutect2, varscan2
- GPR34 | c.975C>G p.V325= | Silent (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- GTF2IRD1 | c.1860C>T p.I620= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs1402326965, COSV56090733; called by mutect2, varscan2
- HELB | c.660C>T p.F220= | Silent (SNP) | VAF 24/105 reads (23%) | catalogued as rs1421930517, COSV56075644; called by muse, mutect2, varscan2
- ITLN2 | c.297G>A p.E99= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV63538133; called by muse, varscan2
- KLHL32 | c.1131C>T p.S377= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV100987384; called by muse, mutect2, varscan2
- LSM14A | c.1365T>C p.Y455= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV70885598; called by muse, mutect2, varscan2
- MAST1 | c.1662C>T p.I554= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV52252736; called by muse, mutect2, varscan2
- MKI67 | c.8406C>T p.G2802= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV64076233; called by muse, mutect2, varscan2
- MPO | c.1053G>A p.R351= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV56565802; called by muse, varscan2
- MUC16 | c.9720C>T p.T3240= | Silent (SNP) | VAF 49/183 reads (27%) | catalogued as COSV67485875; called by muse, mutect2, varscan2
- MYOCD | c.2382C>T p.I794= | Silent (SNP) | VAF 28/121 reads (23%) | catalogued as COSV100591551, COSV58509984; called by muse, mutect2, varscan2
- NEDD4 | c.1866C>T p.I622= (on ENST00000508342 / NM_001284338.1; = p.I203= on NM_006154.4) | Silent (SNP) | VAF 27/126 reads (21%) | catalogued as COSV59065574; called by muse, mutect2, varscan2
- NLRP14 | c.1062T>C p.S354= | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as COSV55070897; called by muse, mutect2, varscan2
- OR13C8 | c.351G>A p.T117= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs140558238, COSV58610654; called by mutect2, varscan2
- OR4D1 | c.78C>T p.F26= | Silent (SNP) | VAF 42/176 reads (24%) | catalogued as rs750175042, COSV52125158; called by muse, mutect2, varscan2
- OR4K1 | c.615G>A p.L205= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV53459075; called by mutect2, varscan2
- OR5AR1 | c.144G>A p.L48= | Silent (SNP) | VAF 42/172 reads (24%) | catalogued as COSV57253133; called by mutect2, varscan2
- OR5AS1 | c.891G>A p.V297= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as rs1565026622, COSV57982068; called by mutect2, varscan2
- OR8B12 | c.822C>T p.S274= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as rs764255889, COSV60912592; called by muse, mutect2, varscan2
- OR8G1 | c.186C>T p.F62= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as rs375001219; called by muse, mutect2, varscan2
- PAH | c.39G>A p.R13= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV61019554; called by muse, mutect2, varscan2
- PAMR1 | c.1557C>T p.D519= (on ENST00000619888 / NM_001001991.3; = p.D536= on NM_015430.4) | Silent (SNP) | VAF 27/115 reads (23%) | catalogued as COSV53509911, COSV53515622; called by muse, mutect2, varscan2
- PAX2 | c.1203C>T p.A401= (on ENST00000428433 / NM_003987.5; = p.A378= on NM_000278.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 27/125 reads (22%) | catalogued as COSV62292641; called by muse, mutect2, varscan2
- PBLD | c.447C>T p.V149= | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as COSV53267053; called by muse, mutect2, varscan2
- PEAK1 | c.4329C>T p.S1443= | Silent (SNP) | VAF 38/132 reads (29%) | catalogued as COSV56941456; called by muse, mutect2, varscan2
- PHKA2 | c.783C>T p.S261= | Silent (SNP) | VAF 24/38 reads (63%) | catalogued as COSV66055663; called by muse, mutect2, varscan2
- PKD1L1 | c.4710G>A p.R1570= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV56969814; called by muse, mutect2, varscan2
- PKDREJ | c.1182G>A p.G394= | Silent (SNP) | VAF 24/105 reads (23%) | catalogued as COSV53552151; called by muse, mutect2, varscan2
- PLEKHA4 | c.456C>T p.S152= | Silent (SNP) | VAF 17/117 reads (15%) | catalogued as rs1235162691, COSV99612773; called by muse, mutect2, varscan2
- POLD1 | c.2097C>T p.S699= | Silent (SNP) | VAF 33/118 reads (28%) | catalogued as rs748871980, COSV70954156; called by muse, mutect2, varscan2
- PPFIA2 | c.2652T>G p.L884= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV61049100; called by muse, mutect2
- PTCHD3 | c.876G>A p.R292= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV101438925; called by muse, mutect2, varscan2
- PTPRB | c.867C>A p.P289= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV54250456, COSV99717561; called by muse, mutect2, varscan2
- PTPRR | c.333C>T p.I111= | Silent (SNP) | VAF 33/137 reads (24%) | catalogued as COSV51733158; called by muse, mutect2, varscan2
- RNF112 | c.177C>T p.I59= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs1410732827, COSV71978972; called by muse, mutect2, varscan2
- RYR1 | c.3207C>T p.D1069= | Silent (SNP) | VAF 31/119 reads (26%) | catalogued as COSV62107335; called by muse, mutect2, varscan2
- SCN3A | c.5700G>A p.E1900= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV51820683; called by muse, mutect2, varscan2
- SETD1A | c.1212C>T p.R404= | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as COSV52691414; called by muse, mutect2, varscan2
- SHPK | c.90C>T p.S30= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV50443109; called by mutect2, varscan2
- SLC12A6 | c.2862C>T p.I954= (on ENST00000354181 / NM_001365088.1; = p.I903= on NM_005135.2) | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV51630221; called by muse, mutect2, varscan2
- SLC1A6 | c.558T>C p.F186= | Silent (SNP) | VAF 78/300 reads (26%) | catalogued as COSV55673300; called by muse, mutect2, varscan2
- SLC8A3 | c.198G>A p.E66= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV63525389; called by muse, mutect2, varscan2
- SLC9C2 | c.2193A>T p.A731= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV62948481; called by muse, mutect2, varscan2
- SMARCD1 | c.901C>T p.L301= | Silent (SNP) | VAF 36/110 reads (33%) | catalogued as COSV67412925; called by muse, mutect2, varscan2
- SPAG17 | c.4461G>A p.Q1487= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs1240666215, COSV100308578, COSV60465837; called by muse, mutect2, varscan2
- STPG2 | c.1089G>A p.E363= | Silent (SNP) | VAF 26/140 reads (19%) | catalogued as rs142342055; called by muse, mutect2, varscan2
- SYNPO2L | c.1932G>A p.T644= (on ENST00000394810 / NM_001114133.3; = p.T420= on NM_024875.5) | Silent (SNP) | VAF 53/182 reads (29%) | catalogued as rs1263490541, COSV65738619; called by mutect2, varscan2
- SYT16 | c.1635A>G p.G545= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV70858939; called by muse, mutect2, varscan2
- SZT2 | c.4872C>T p.P1624= (on ENST00000634258 / NM_001365999.1; = p.P1567= on NM_015284.4) | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as rs766275248, COSV65168535; called by mutect2, varscan2
- TACC2 | c.7095A>G p.Q2365= (on ENST00000334433; = p.Q443= on NM_006997.4) | Silent (SNP) | VAF 60/232 reads (26%) | catalogued as COSV53287666; called by muse, mutect2, varscan2
- TAS2R38 | c.372C>T p.F124= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs782592505, COSV71885828; called by muse, mutect2, varscan2
- TCF7L2 | c.1557C>T p.S519= (on ENST00000355995 / NM_001367943.1; = p.S496= on NM_030756.5) | Silent (SNP) | VAF 49/258 reads (19%) | catalogued as rs765693671, COSV53345816; called by muse, mutect2, varscan2
- TNN | c.3381G>A p.R1127= | Silent (SNP) | VAF 37/150 reads (25%) | catalogued as rs1311887871, COSV53433329; called by muse, mutect2, varscan2
- TRRAP | c.6669C>T p.F2223= (on ENST00000359863 / NM_001244580.1; = p.F2205= on NM_003496.3) | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV62852153; called by muse, mutect2, varscan2
- ZBTB7A | c.246C>T p.A82= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs560721320, COSV100475715, COSV59326019; called by mutect2, varscan2
- ZNF106 | c.1296C>T p.C432= | Silent (SNP) | VAF 65/210 reads (31%) | catalogued as COSV55520769; called by muse, mutect2, varscan2
- ZYG11B | c.1653C>T p.F551= | Silent (SNP) | VAF 21/129 reads (16%) | catalogued as rs990121781, COSV53756299; called by muse, mutect2, varscan2
- ABCC9 | chr12:21801163 G>A | 3'Flank (SNP) | VAF 24/78 reads (31%) | catalogued as COSV53982741; called by muse, varscan2
- AL109984.1 | n.186+1557G>A | Intron (SNP) | VAF 23/76 reads (30%) | catalogued as COSV63754282; called by mutect2, varscan2
- CTBP2 | c.59-2156C>T | Intron (SNP) | VAF 11/44 reads (25%) | catalogued as COSV100456602; called by mutect2, varscan2
- KCNK1 | c.356-16562C>T | Intron (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- NDUFV3 | c.170-5553G>T | Intron (SNP) | VAF 36/138 reads (26%) | catalogued as COSV61088333; called by muse, varscan2
- TTN | c.10360+4211C>T | Intron (SNP) | VAF 18/88 reads (20%) | catalogued as rs990157560, COSV59862241; called by mutect2, varscan2
- ZNF99 | c.*58C>T | 3'UTR (SNP) | VAF 8/37 reads (22%) | catalogued as COSV68054801; called by mutect2, varscan2
